Surgical pathology report (de-identified scan), TCGA case TCGA-BP-4971, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site MSKCC, specimen TCGA-BP-4971-01A (Primary Tumor).

[page 1 of 3]
Accession #:

Date of Procedure:

Date of Receipt:

Date of Report:

Account #:

Billing Type:

Additional Copy to:

Ref. Source:

TCGA - BP - 4971

Clinical Diagnosis & History:

with large right renal mass - g250 (+).

Specimens Submitted:

- 1: SP: Kidney, right, total nephrectomy
- 2: SP: Lymph node, precaval, paracaval and retrocaval, excision
- 3: SP: Adrenal gland, right, adrenalectomy

DIAGNOSIS:

1. SP: Kidney, right, total nephrectomy

Tumor Type:

Renal cell carcinoma - Conventional (clear cell) type

Fuhrman Nuclear Grade:

Nuclear grade III/IV

Tumor Size:

Greatest diameter is 8.1 cm.

Local Invasion (for renal cortical types):

Involves renal sinus fat

Renal Vein Invasion:

Vessels with muscular wall are involved by tumor

Surgical Margins:

Free of tumor

Non-Neoplastic Kidney:

Focal granulomatous reaction and glomerulosclerosis

Adrenal Gland:

Not identified

Lymph Nodes:

Not identified

Staging for renal cell carcinoma/oncocytoma:

pT3a Tumor invades the adrenal gland or perinephric tissues but not beyond Gerota's fascia

2. SP: Lymph node, precaval, paracaval and retrocaval, excision

Lymph Nodes:

Not involved

Number of nodes examined: 5

[page 2 of 3]
[REDACTED]

Benign segment of vessel is also identified.

3. SP: Adrenal gland, right, adrenalectomy [REDACTED]
Benign adrenal gland

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

[REDACTED]

Special Studies:

Result	Special Stain	Comment
	AE1:AE3	
	NEG CONT	
	IMM RECUT	
	AE1:AE3	
	NEG CONT	
	IMM RECUT	
	AE1:AE3	

Gross Description:

[REDACTED]

1). The specimen is received fresh, previously incised and placed in formalin, labeled "Right kidney" and consists of a total nephrectomy specimen with an attached ureter, renal vessels and perinephric fat, weighing 642 g post fixation. The external surface has been inked black. The kidney measures 12.5 x 8.3 x 4.6 cm. The attached ureter measures 3.3 cm in length and 0.4 cm in diameter in greatest dimension. The ureteral margin is identified and appears grossly uninvolved by tumor. On opening, the ureter is lined by a pink-tan soft faintly corrugated tissue. The attached renal vessels are identified, with a slight area of firmness identified at the distal aspect of the smaller vessel, and the margins appear grossly uninvolved by tumor. The capsular surface is smooth and pink-tan. The kidney is bivalved to reveal a pseudo encapsulated yellow-red tumor mass measuring 8.1 x 7.5 x 4.3 cm, occupying the superior and mid poles of the kidney, which appears to be partially surrounded by a rim of dense white fibrous tissue. The mass appears to focally protrude into the sinus fat with possible focal invasion, but does not grossly involve the renal pelvis. At the center of the mass, an ill-defined firm white-tan focally hemorrhagic scarred area is identified measuring 2.8 x 2.3 cm in greatest dimension. Focal areas of necrosis are also identified. The mass abuts the renal calyces and serial sectioning reveals possible invasion by soft friable red-tan tumor tissue. The attached perinephric fat has been inked black and on cut section reveals a focal area of possible extracapsular extension into the fat. The inked margins do not appear to be grossly involved by tumor. Sectioning through the remainder of the kidney reveals a pink brown parenchyma, which appears grossly unremarkable. The corticomedullary junction is well delineated, with the cortex measuring 0.6 cm in width. Sectioning through the perinephric fat reveals no grossly identifiable lymph nodes. Representative sections of the specimen are submitted to TPS for permanent section and photographs have been taken.

Summary of sections:

VM – vessel margin shave
UM – ureter margin shave
TWP – tumor with pelvis
TWS – tumor with sinus
TWN – tumor with normal
RST – representative sections tumor
RS – representative sections normal kidney
TWC – tumor with possible extension into calyces
TWF – tumor with fat

[REDACTED]

2). The specimen is received in formalin, labeled "Precaval, paracaval lymph nodes and retrocaval lymph nodes" and consists of multiple hemorrhagic lymph nodes ranging in size from 0.8 to 1.7 cm. A smooth pink-tan tubular piece of vascular tissue is also

[page 3 of 3]
identified measuring 3.0 x 0.5 cm, with each end stapled. Cut section reveals a patent lumen. Representative sections of the vein are submitted in the lymph nodes, completely sectioned at 3 mm intervals and submitted.

Summary of sections:

V -- representative sections blood vessel
BN1 -- bisected lymph node number one
BN2 -- bisected lymph node number two
BN3 -- bisected lymph node number three
TLN -- trisected lymph node
RSN -- lymph node at 3 mm intervals

3). The specimen is received in formalin, labeled "Right adrenal gland" and consists of a total adrenalectomy specimen, with attached adipose tissue measuring 51 x 2.9 x 1.0 cm and weighing 10.5 g post fixation. The external surface is inked black, and serial sections reveal a rim of bright yellow soft tissue, with central areas of tan and dark red soft tissue noted. Representative sections are submitted.

Summary of sections:

RS -- representative sections

Summary of Sections:

Part 1: SP: Kidney, right, total nephrectomy

Block	Sect. Site	PCs
1	rs	1
5	rst	5
2	twc	2
1	twf	1
1	twn	1
1	twp	1
2	tws	2
1	um	1
1	vm	1

Part 2: SP: Lymph node, precaval, paracaval and retrocaval, excision

Block	Sect. Site	PCs
1	bn1	1
1	bn2	1
1	bn3	1
1	rsn	1
1	tlh	1
1	v	1

Part 3: SP: Adrenal gland, right, adrenalectomy

Block	Sect. Site	PCs
4	rs	4

Source: NCI Genomic Data Commons file 2b5fc2ba-8d5f-4e47-a733-118c13e07907 (TCGA-BP-4971.AFA4B302-55A6-410D-94F9-B6B2FA4BD9C4.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).